Surgical pathology report (de-identified scan), TCGA case TCGA-V5-AASX, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-AASX-01A (Primary Tumor).

Patient Name:		DOB:		Accession #:	
Medical Record #:		Age:		Patient ID:	
Clinician:		Sex:		Date Obtained:	
Clinician Phone:				Date Received:	
Specimen:	Esophagus Biopsy				
Pertinent History:	Dysphagia, weight loss				
ICD-9 Codes:					

Final Pathologic Diagnosis

DISTAL ESOPHAGUS, BIOPSY: MODERATELY DIFFERENTIATED ADENOCARCINOMA, SEE COMMENT.

COMMENT:

THE BIOPSIES ARE DIAGNOSTIC OF ADENOCARCINOMA AND WITH THE PRESENCE OF INTESTINAL METAPLASIA, ORIGIN IN PREEXISTING BARRETT'S ESOPHAGUS IS FAVORED.

THE SLIDES ARE REVIEWED BY AND WE CONCUR WITH THIS INTERPRETATION.

THE RESULTS ARE CALLED TO ON AT APPROXIMATELY:

Electronically verified by:

- Department of Pathology

Gross Examination

Received are multiple fragments of tan, grey tissue measuring up to 0.1 cm which are submitted in cassette 1A.

Microscopic Description

Sections show fragments of esophageal mucosa which contains a malignant epithelial neoplasm. The neoplasm is composed of malignant epithelial cells which form poorly formed glandular structures and infiltrate within inflamed fibromuscular stroma. There are fragments within the biopsies of benign squamous epithelium and glandular epithelium with intestinal metaplasia.

ICD-O-3

Adenocarcinoma NOS 8140/3

Site Esophagus, distal third
015.5

JW 2/18/14

Source: NCI Genomic Data Commons file 3f8046ce-122c-42a4-9086-8d1c6cecf153 (TCGA-V5-AASX.0C4B06F7-3B4E-422B-A73D-9393CC4E56FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).